Surgical pathology report (de-identified scan), TCGA case TCGA-DK-A3WX, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DK-A3WX-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient Name:

Med. Rec. #:

DOB: (Age:

Gender:

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Clinical Diagnosis & History:

History of bladder cancer.

ICD-O-3
carcinoma, urothelial, NOS
8120/3

Specimens Submitted:

1: Left lateral bladder wall, TURBT

2: Depth of tumor, TURBT

3: Base of tumor, TURBT

Site: bladder, wall, lateral

C67.2

5-23-12
RP

DIAGNOSIS:

1. Left lateral bladder wall, TURBT:

Part # 1

Tumor Type:

Invasive urothelial carcinoma, NOS
with extensive necrosis

Histologic Grade:

High grade

Pattern of growth of the non-invasive component:

No in situ carcinoma

Local Invasion:

Muscularis propria

Vascular Invasion:

Not identified

2. Depth of tumor, TURBT:

Part # 2

Tumor Type:

Invasive urothelial carcinoma, NOS
with focal squamous differentiation

Histologic Grade:

High grade

Pattern of growth of the non-invasive component:

No in situ carcinoma

Local Invasion:

Muscularis propria

Vascular Invasion:

Not identified

3. Base of tumor, TURBT:

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

Part # 3

Tumor Type:

Invasive urothelial carcinoma, NOS

Histologic Grade:

High grade

Pattern of growth of the non-invasive component:

No in situ carcinoma

Local Invasion:

Muscularis propria

Vascular Invasion:

Not identified

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

- 1) The specimen is received in Hank's solution, labeled "Left lateral bladder wall", and consists of multiple piece(s) of irregular tan-brown soft tissue fragment measuring 15x0.5x0.2cm. The specimen entirely submitted in 5 cassettes. taken.
- 2) The specimen is received in Hank's solution, labeled "Depth of tumor", and consists of multiple piece(s) of irregular tan-brown soft tissue fragment measuring 13x0.5x0.4cm. The specimen entirely submitted in 1 cassettes.
- 3) The specimen is received in formalin, labeled "Base of tumor", and consists of 2 piece(s) of irregular tan-brown soft tissue fragment measuring 12x0.5x0.5cm. The specimen entirely submitted in 1 cassette.

Summary of Sections:

Part 1: Left lateral bladder wall, TURBT

Block	Sect. Site	PCs
5	{not entered}	27

Part 2: Depth of tumor, TURBT

Block	Sect. Site	PCs
1	{not entered}	5

Part 3: Base of tumor, TURBT

Block	Sect. Site	PCs
1	{not entered}	2

Source: NCI Genomic Data Commons file a32f2bcd-934e-4cdf-b34a-4c339d02e2c7 (TCGA-DK-A3WX.9E6A2855-20DB-4EFD-ADFF-8B82CD356533.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).